Surgical pathology report (de-identified scan), TCGA case TCGA-CM-6169, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-6169-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

[REDACTED] with adenocarcinoma of ascending colon.

Specimens Submitted:

- 1: SP: Right hemicolectomy
- 2: SP: Small bowel

DIAGNOSIS:

- 1. SP: Right hemicolectomy:

Tumor Type:

Adenocarcinoma

Histologic Grade:

Moderately differentiated

Tumor Location:

Cecum

Tumor Size:

Length is 3.7 cm

Width is 4.0 cm

Tumor Budding:

Focal

Increased Tumor Infiltrating Lymphocytes:

Absent

Precursor Lesions:

Not identified

Deepest Tumor Invasion:

Subserosal adipose tissue and/or mesenteric fat

Gross Tumor Perforation:

Not identified

Lymphovascular Invasion:

Identified

Large Venous Invasion:

Identified

Perineural Invasion:

Identified

Surgical Margins:

Free of tumor

Polyyps/Mucosa Dysplasia (away from the carcinoma):

Not Identified

Non-Neoplastic Bowel:

Unremarkable

** Continued on next page **

[page 2 of 3]
Appendix:

Unremarkable

Lymph Nodes:

Number with metastasis: 0

Total number examined: 19

Tumor deposits in pericorectal soft tissue:

Not Identified

Tumor Staging (AJCC 7th Edition):

pT3 (Tumor invades through the muscularis propria into pericorectal tissues)

Lymph Node Stage (AJCC 7th Edition):

N0 (No regional lymph node metastasis)

2. SMALL INTESTINE; RESECTION

- SEGMENT OF SMALL INTESTINE WITH NO PATHOLOGIC DIAGNOSIS.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Gross Description:

1). The specimen is received fresh, labeled "Right colon" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures 8.5 cm in length and 4.5 cm in circumference at the proximal resected margin. The remaining colon measures 29.0 in length with a circumference of 7.0 cm at the distal resected margin. The attached appendix measures 4.0 cm in length and averages 0.5 cm in diameter. The appendiceal and intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 4.5 cm in thickness. The specimen is opened to reveal a mass lesion measuring 3.7 cm in length and 4.0 cm in width. The mass is located in the large bowel 0.3 cm from the ileocecal valve, 11.0 cm from the proximal margin and 24 cm from the distal margin. Sectioning shows that the tumor grossly invades through the muscularis and serosa. The depth of invasion is 0.3 cm grossly. The remaining mucosa is tan-brown with the normal folds. There are multiple minute polypoid lesions on the terminal ileum mucosa. The attached adipose tissue is thoroughly examined and all identified lymph nodes are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

P - proximal margin shave

D - distal margin shave

T - tumor

A - appendix representative sections

RP-- polypoid lesion from terminal ileum

RS -representative sections

PD--possible diverticulum

** Continued on next page **

[page 3 of 3]
LN - lymph nodes
BLN - bisected lymph nodes

2. The specimen is received fresh labeled "small bowel". It consists of an unoriented segment of small bowel measuring 21.5 cm in length and 3.6 cm in circumference. The serosal and mucosal surface is grossly unremarkable. Representative sections are submitted.

Summary of sections:
SM1 - one margin
SM2 - the other margin
RS - representative sections

Summary of Sections:
Part 1: SP: Right hemicolectomy

Block	Sect. Site	PCs
1	A	3
2	DM	4
8	LN	24
1	PD	1
1	PM	2
2	RP	6
2	RS	4
7	T	9

Part 2: SP: Small bowel

Block	Sect. Site	PCs
2	RS	2
1	SM1	1
1	SM2	1

** End of Report **

Source: NCI Genomic Data Commons file 29c07842-d70c-4237-91cc-6fe7ca62d91a (TCGA-CM-6169.94244F00-1696-46E7-88AF-D316A5C238FB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).